Somatic mutation profile of tumor specimen MMRF_1587_2_BM_CD138pos (aliquot MMRF_1587_2_BM_CD138pos_T1_KHS5U_L11626) from MMRF case MMRF_1587, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.6 years (27,232 days).
Specimen MMRF_1587_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89da85c3-ee2a-475e-9426-70d965d636fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1587_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1587_1_PB_CD3pos_C2_KBS5U_L04126; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/827da6c9-ea6c-4fdd-9fe9-7d88d5fe2752

The open-access MAF lists 302 somatic variants for this specimen: 125 protein-altering or splice-affecting, 33 silent, 144 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, 3'UTR 85, Intron 34, Silent 33, Nonsense Mutation 10, 5'UTR 8, 3'Flank 8, Splice Region 5, Frame Shift Del 5, RNA 5, 5'Flank 4, Splice Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 130/297 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABAT | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174585175, COSV51624298, COSV99076779; called by muse, mutect2
- ACAA1 | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 80/135 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100086450; called by muse, mutect2, varscan2
- ARHGAP35 | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.037); catalogued as rs759688841, COSV68333736; called by muse, mutect2
- BBS9 | c.1756G>A p.A586T (on ENST00000242067 / NM_001348036.1; = p.A546T on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs1269719837; called by muse, mutect2
- BICDL1 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs780597636; called by muse, mutect2, varscan2
- CASP12 | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 105/174 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100998284; called by muse, mutect2, varscan2
- CD74 | c.125+1G>A p.X42_splice | Splice Site (SNP) | VAF 44/87 reads (51%) | catalogued as rs112138942; called by muse, mutect2, varscan2
- CDH10 | c.2048A>G p.E683G | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1373368879, COSV52579594, COSV52600990; called by muse, mutect2, varscan2
- CDH8 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866984859, COSV54865725; called by muse, mutect2, varscan2
- CHD5 | c.3755G>A p.S1252N | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV52425016; called by muse, mutect2
- CHST12 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 114/248 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs905098497, COSV51676142; called by muse, mutect2, varscan2
- CNTNAP2 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100671653; called by muse, mutect2, varscan2
- EVX2 | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs1236676999, COSV100420580; called by muse, mutect2
- GJA10 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104428227; called by muse, mutect2, varscan2
- GTPBP8 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 162/307 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs779918051; called by mutect2, varscan2
- H1-5 | c.266G>C p.S89T | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV100137908; called by muse, mutect2
- H3C7 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1331046387; called by muse, mutect2
- HK3 | c.2747del p.R916Pfs*5 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as COSV52841302; called by mutect2, varscan2
- HYDIN | c.7574G>A p.R2525H | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756437118, COSV59262649; called by muse, mutect2, varscan2
- IBTK | c.2121dup p.G708Rfs*5 | Frame Shift Ins (INS) | VAF 52/129 reads (40%) | catalogued as rs772241425; called by mutect2, pindel, varscan2
- IGHV1-69 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 14/14 reads (100%) | catalogued as rs558289670; called by mutect2, varscan2
- IGHV2-70 | c.346T>C p.C116R | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs570255228; called by muse, mutect2, varscan2
- IGHV3-33 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 83/95 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs752557018; called by muse, varscan2
- IGKV4-1 | c.354T>G p.Y118* | Nonsense Mutation (SNP) | VAF 56/61 reads (92%) | catalogued as rs374092750; called by muse, mutect2
- KANSL1 | c.902T>A p.L301* | Nonsense Mutation (SNP) | VAF 107/197 reads (54%) | catalogued as rs1189248208; called by muse, mutect2, varscan2
- KCNG1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs368678625; called by muse, mutect2, varscan2
- KCNG3 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs372497614; called by muse, mutect2
- KIF25 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs750565768; called by muse, varscan2
- LNX1 | c.844C>G p.P282A (on ENST00000263925 / NM_001126328.3; = p.P186A on NM_032622.2) | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV55785915; called by muse, mutect2, varscan2
- MATK | c.861C>A p.N287K (on ENST00000310132 / NM_139355.3; = p.N288K on NM_002378.4) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762816997; called by muse, mutect2, varscan2
- MSLNL | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as COSV53507123; called by muse, mutect2, varscan2
- MYBBP1A | c.3736G>C p.A1246P | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as COSV54595948; called by muse, mutect2, varscan2
- NOS1AP | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV62633920; called by muse, mutect2
- PCDH8 | c.2050C>A p.R684S | Missense Mutation (SNP) | VAF 66/75 reads (88%) | SIFT tolerated (0.52); PolyPhen benign (0.439); catalogued as rs1290037589; called by muse, mutect2, varscan2
- PCDHB6 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 152/402 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs904708904, COSV50695334; called by muse, mutect2, varscan2
- PLOD2 | c.405A>C p.K135N | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.889); catalogued as COSV99282313; called by muse, mutect2
- PML | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1247431420; called by muse, mutect2, varscan2
- PRG3 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs752005955; called by muse, mutect2, varscan2
- PRKD1 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 115/120 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201010570, COSV100119643; called by muse, mutect2, varscan2
- PROKR1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 224/233 reads (96%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs143892402, COSV58136477; called by muse, mutect2, varscan2
- PTPRU | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774083255; called by muse, mutect2, varscan2
- RCCD1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.014); catalogued as rs1324346014, COSV67793637; called by muse, mutect2
- RLIM | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 83/144 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV60328537; called by muse, mutect2, varscan2
- ROBO3 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 191/296 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101185218; called by muse, mutect2, varscan2
- SERINC2 | c.433G>A p.V145M (on ENST00000373709 / NM_178865.5; = p.V149M on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140666908; called by muse, mutect2, varscan2
- SLC14A2 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746143236; called by muse, mutect2
- SP140 | c.704C>A p.S235* | Nonsense Mutation (SNP) | VAF 71/84 reads (85%) | catalogued as rs190133390; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 67/120 reads (56%) | PolyPhen possibly damaging (0.72); catalogued as rs757163221; called by muse, mutect2, varscan2
- TADA3 | c.810G>A p.E270= | Splice Region (SNP) | VAF 27/53 reads (51%) | catalogued as rs1277993137, COSV57333420; called by muse, mutect2, varscan2
- UBR5 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 19/169 reads (11%) | catalogued as COSV55288573; called by muse, mutect2, varscan2
- ANO3 | c.1991T>C p.V664A | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP1A3 | c.2800T>G p.W934G (on ENST00000545399 / NM_001256214.2; = p.W921G on NM_152296.5) | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- BHLHE41 | c.998_1028del p.G333Afs*160 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- BICC1 | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 85/89 reads (96%) | called by muse, mutect2, varscan2
- BMPER | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2
- BTBD3 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- C4orf33 | c.26G>C p.W9S | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH11 | c.2074C>A p.P692T | Missense Mutation (SNP) | VAF 151/356 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CDK13 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- CFAP77 | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); called by muse, mutect2
- CHRM2 | c.948A>C p.K316N | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CNGA4 | c.919T>G p.Y307D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, varscan2
- DALRD3 | c.1279C>A p.P427T (on ENST00000341949 / NM_001009996.3; = p.P260T on NM_018114.5) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNMT3B | c.2276G>A p.C759Y | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DST | c.6273A>C p.E2091D | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EBF3 | c.809C>G p.P270R (on ENST00000355311 / NM_001375392.1; = p.P261R on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/73 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ECHDC1 | c.406A>C p.M136L (on ENST00000531967 / NM_001139510.1; = p.M130L on NM_001002030.2) | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ECT2L | c.2384G>A p.C795Y | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FKBPL | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.273); called by muse, mutect2
- GAK | c.237C>G p.N79K | Missense Mutation (SNP) | VAF 47/412 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- GLI2 | c.1300C>A p.Q434K (on ENST00000361492 / NM_001374353.1; = p.Q451K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- H3C10 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 96/217 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- HECW1 | c.3334C>T p.P1112S | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- HUWE1 | c.12851C>T p.A4284V | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IDE | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2
- IGHV2-70D | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, varscan2
- IGHV2-70D | c.238T>G p.Y80D | Missense Mutation (SNP) | VAF 102/106 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHV2-70D | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 49/49 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, varscan2
- IGKV4-1 | c.219_226del p.I74Gfs*10 | Frame Shift Del (DEL) | VAF 56/74 reads (76%) | called by pindel, varscan2
- INO80D | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 88/200 reads (44%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.802C>G p.R268G (on ENST00000485419 / NM_001197113.1; = p.R192G on NM_014575.3) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.057); called by muse, varscan2
- IQGAP3 | c.2427A>C p.Q809H | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- JAK1 | c.2970G>C p.G990= | Splice Region (SNP) | VAF 145/275 reads (53%) | called by muse, mutect2, varscan2
- KCNMB4 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 128/300 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNT1 | c.1278C>A p.A426= (on ENST00000488444; = p.A445= on NM_020822.3) | Splice Region (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- KMT2D | c.8587G>C p.G2863R | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- L2HGDH | c.1205C>A p.A402D | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LAMA5 | c.300C>T p.G100= | Splice Region (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- LONRF1 | c.2013del p.E672Rfs*27 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- LRRD1 | c.762A>T p.E254D | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MED12L | c.3872T>C p.I1291T | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MGAT4C | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MMP13 | c.1164_1170del p.F388Lfs*30 | Frame Shift Del (DEL) | VAF 125/222 reads (56%) | called by mutect2, pindel, varscan2
- MRM1 | c.636+1G>C p.X212_splice | Splice Site (SNP) | VAF 67/156 reads (43%) | called by muse, mutect2, varscan2
- MYO18A | c.1616T>A p.L539Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- NOL6 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 136/287 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- NUBP2 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR10G7 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 176/377 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- OR14A2 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 421/430 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- PLEKHG4 | c.725A>C p.E242A | Missense Mutation (SNP) | VAF 168/319 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- POU3F4 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 94/95 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R26 | c.2972G>C p.G991A | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCA | c.1294G>C p.V432L | Missense Mutation (SNP) | VAF 114/224 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRSS22 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PTBP2 | c.550G>A p.A184T (on ENST00000426398 / NM_001300986.2; = p.A176T on NM_021190.4) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RASGEF1B | c.438+4G>T | Splice Region (SNP) | VAF 4/93 reads (4%) | called by muse, mutect2
- RBM6 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- REM1 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- REX1BD | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RGMA | c.696C>A p.Y232* | Nonsense Mutation (SNP) | VAF 170/338 reads (50%) | called by muse, mutect2, varscan2
- RLF | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RPTOR | c.3706G>A p.V1236M | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2
- RSAD2 | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2
- SHANK1 | c.4938T>A p.H1646Q | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ST6GALNAC6 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 75/147 reads (51%) | PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- STARD4 | c.116C>G p.T39S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SUPT6H | c.5172G>T p.M1724I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.38); called by muse, mutect2
- TCF19 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TG | c.8233T>G p.L2745V | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TYRP1 | c.1409-7_1409-2del p.X470_splice | Splice Site (DEL) | VAF 72/162 reads (44%) | called by pindel, varscan2
- UMODL1 | c.3866C>A p.T1289N (on ENST00000408910 / NM_001004416.2; = p.T1417N on NM_173568.3) | Missense Mutation (SNP) | VAF 143/165 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- USH1C | c.100C>A p.H34N | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.409); called by muse, mutect2
- VWA8 | c.1378T>G p.F460V | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2
- ZNFX1 | c.999C>G p.Y333* | Nonsense Mutation (SNP) | VAF 72/143 reads (50%) | called by muse, mutect2, varscan2
- ABCA2 | c.5937C>T p.F1979= (on ENST00000614293; = p.F1949= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/213 reads (40%) | catalogued as COSV55801708; called by muse, mutect2, varscan2
- ALPI | c.798G>A p.V266= | Silent (SNP) | VAF 57/119 reads (48%) | called by muse, mutect2, varscan2
- ARR3 | c.252A>T p.P84= | Silent (SNP) | VAF 109/110 reads (99%) | called by muse, mutect2, varscan2
- ATP13A4 | c.2781C>T p.S927= | Silent (SNP) | VAF 43/71 reads (61%) | called by muse, mutect2, varscan2
- B3GAT2 | c.723C>T p.A241= | Silent (SNP) | VAF 150/330 reads (45%) | called by muse, mutect2, varscan2
- C1orf21 | c.180A>G p.Q60= | Silent (SNP) | VAF 136/293 reads (46%) | called by muse, mutect2, varscan2
- CEACAM7 | c.501C>T p.T167= | Silent (SNP) | VAF 67/153 reads (44%) | called by muse, mutect2, varscan2
- CEP112 | c.234G>A p.A78= | Silent (SNP) | VAF 121/242 reads (50%) | catalogued as rs182724164; called by muse, mutect2, varscan2
- COL25A1 | c.24G>T p.G8= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV67649814; called by muse, mutect2, varscan2
- FUT8 | c.1527C>T p.A509= (on ENST00000360689 / NM_001371534.1; = p.A346= on NM_004480.4) | Silent (SNP) | VAF 146/155 reads (94%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.942C>T p.R314= | Silent (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.144T>C p.S48= | Silent (SNP) | VAF 70/75 reads (93%) | catalogued as rs189675840; called by muse, varscan2
- ITPRIPL2 | c.9G>A p.V3= | Silent (SNP) | VAF 102/180 reads (57%) | called by muse, mutect2, varscan2
- KDR | c.3801A>G p.E1267= | Silent (SNP) | VAF 74/169 reads (44%) | called by muse, mutect2, varscan2
- MAP3K4 | c.1404T>C p.D468= | Silent (SNP) | VAF 75/160 reads (47%) | called by muse, mutect2, varscan2
- MEN1 | c.1272C>T p.G424= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV53646697; called by muse, mutect2, varscan2
- MFAP1 | c.534G>A p.E178= | Silent (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
- MSR1 | c.882A>C p.G294= | Silent (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- NIBAN2 | c.480C>A p.L160= | Silent (SNP) | VAF 83/191 reads (43%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.216G>A p.L72= | Silent (SNP) | VAF 335/342 reads (98%) | called by muse, mutect2, varscan2
- PCDHGC3 | c.792A>G p.V264= | Silent (SNP) | VAF 191/404 reads (47%) | catalogued as rs754076231; called by muse, mutect2, varscan2
- PCSK1 | c.1014C>T p.G338= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs1307895014; called by muse, mutect2, varscan2
- PDE1C | c.630C>A p.V210= | Silent (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- PIKFYVE | c.2403A>G p.K801= | Silent (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
- PPARGC1B | c.2343C>A p.A781= | Silent (SNP) | VAF 104/194 reads (54%) | called by muse, mutect2, varscan2
- RGS22 | c.3102A>G p.Q1034= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs374356639; called by muse, mutect2, varscan2
- RGS8 | c.450A>T p.V150= (on ENST00000367556 / NM_001369564.2; = p.V168= on NM_033345.3) | Silent (SNP) | VAF 14/303 reads (5%) | called by muse, mutect2
- RTEL1 | c.2190C>T p.P730= | Silent (SNP) | VAF 24/263 reads (9%) | catalogued as rs144933599; called by muse, mutect2
- SKOR1 | c.2817C>T p.A939= | Silent (SNP) | VAF 127/301 reads (42%) | catalogued as rs748947613; called by muse, mutect2, varscan2
- SMC1A | c.651A>T p.V217= | Silent (SNP) | VAF 75/77 reads (97%) | called by muse, mutect2, varscan2
- SMIM9 | c.51T>C p.T17= | Silent (SNP) | VAF 303/308 reads (98%) | called by muse, mutect2, varscan2
- TCF4 | c.174C>T p.S58= | Silent (SNP) | VAF 76/165 reads (46%) | called by muse, mutect2, varscan2
- TTC8 | c.246G>A p.T82= (on ENST00000338104 / NM_001288781.1; = p.T92= on NM_144596.4) | Silent (SNP) | VAF 78/94 reads (83%) | catalogued as rs574914287; called by muse, mutect2, varscan2
- ABCB1 | c.*171C>T | 3'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- ABCC13 | n.3965C>T | RNA (SNP) | VAF 90/203 reads (44%) | catalogued as rs983835409; called by muse, mutect2, varscan2
- ACSM5 | c.*858dup | 3'UTR (INS) | VAF 6/14 reads (43%) | called by mutect2, pindel, varscan2
- ACTR1B | c.-106C>A | 5'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.-151+1813G>A | Intron (SNP) | VAF 91/162 reads (56%) | called by muse, mutect2, varscan2
- AGPAT1 | c.*1001G>A | 3'UTR (SNP) | VAF 12/34 reads (35%) | catalogued as rs147503745; called by muse, mutect2, varscan2
- AGPAT4 | c.348+4932G>T | Intron (SNP) | VAF 82/169 reads (49%) | called by muse, mutect2, varscan2
- AHCYL2 | c.*2759A>G | 3'UTR (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73828042 G>C | 3'Flank (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- AL441992.2 | c.*276C>A | 3'UTR (SNP) | VAF 100/237 reads (42%) | called by muse, mutect2, varscan2
- AMBRA1 | c.*385G>T | 3'UTR (SNP) | VAF 74/161 reads (46%) | called by muse, mutect2, varscan2
- ANK1 | c.*1214C>G | 3'UTR (SNP) | VAF 27/257 reads (11%) | called by muse, mutect2, varscan2
- ANTXR1 | c.952-6788G>C | Intron (SNP) | VAF 135/302 reads (45%) | called by muse, varscan2
- ANTXR1 | c.952-6577G>A | Intron (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- ANTXR1 | c.952-6395G>T | Intron (SNP) | VAF 32/71 reads (45%) | called by muse, varscan2
- ANTXR1 | c.952-6326G>C | Intron (SNP) | VAF 40/100 reads (40%) | catalogued as rs1268943075; called by muse, varscan2
- ANXA2R | c.-1174T>G | 5'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- ANXA4 | c.397+63G>A | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- AP3S1 | chr5:115841570 G>C | 5'Flank (SNP) | VAF 17/336 reads (5%) | catalogued as rs375881720; called by muse, mutect2
- ARHGAP44 | c.2317+55C>T | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.535-189C>A | Intron (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- ARL5B | c.*3499C>G | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- ASXL1 | c.719-430T>G | Intron (SNP) | VAF 13/34 reads (38%) | catalogued as rs1298873293; called by muse, mutect2, varscan2
- ATL2 | c.*795A>G | 3'UTR (SNP) | VAF 53/93 reads (57%) | called by muse, mutect2, varscan2
- ATP4A | c.*343C>G | 3'UTR (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2, varscan2
- ATP6V0B | chr1:43974783 G>A | 5'Flank (SNP) | VAF 12/190 reads (6%) | catalogued as rs1186235110; called by muse, mutect2
- B4GALT1 | c.*2257A>G | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021401 G>C | 5'Flank (SNP) | VAF 82/173 reads (47%) | catalogued as rs547304687, COSV55852870; called by muse, mutect2, varscan2
- BNC1 | c.*1273G>A | 3'UTR (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- BVES | c.*3930G>A | 3'UTR (SNP) | VAF 17/118 reads (14%) | catalogued as rs576283952; called by muse, mutect2, varscan2
- C11orf40 | n.527G>A | RNA (SNP) | VAF 77/156 reads (49%) | catalogued as rs116086812, COSV56891862; called by muse, mutect2, varscan2
- C11orf87 | c.*1365dup | 3'UTR (INS) | VAF 83/146 reads (57%) | called by mutect2, pindel, varscan2
- C1orf216 | c.*498A>G | 3'UTR (SNP) | VAF 118/260 reads (45%) | called by muse, mutect2, varscan2
- CDK8 | c.456+5789G>C | Intron (SNP) | VAF 191/195 reads (98%) | called by muse, mutect2, varscan2
- CEP290 | c.1825-369A>G | Intron (SNP) | VAF 60/130 reads (46%) | called by muse, mutect2, varscan2
- CHST15 | c.*1614T>G | 3'UTR (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- CHTOP | c.541+566G>A | Intron (SNP) | VAF 99/207 reads (48%) | catalogued as rs1165251311; called by muse, mutect2, varscan2
- COA1 | c.-38-1094A>G | Intron (SNP) | VAF 58/122 reads (48%) | called by muse, mutect2, varscan2
- COP1 | c.-213C>T | 5'UTR (SNP) | VAF 8/191 reads (4%) | catalogued as rs990958889; called by muse, mutect2
- CXXC4 | c.*2326A>G | 3'UTR (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- CYP4F24P | n.82C>A | RNA (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- DAAM1 | c.*1523G>C | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- DDIT4L | c.*1484C>T | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2
- DEFB118 | c.*423G>C | 3'UTR (SNP) | VAF 19/65 reads (29%) | catalogued as rs1048152088; called by muse, mutect2, varscan2
- DENND3 | c.*1506A>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- DGKD | c.157-2302C>T | Intron (SNP) | VAF 128/261 reads (49%) | catalogued as rs1362105583; called by muse, mutect2, varscan2
- DLK1 | c.-9C>T | 5'UTR (SNP) | VAF 67/69 reads (97%) | called by muse, mutect2, varscan2
- DMD | c.*689A>G | 3'UTR (SNP) | VAF 10/10 reads (100%) | called by muse, mutect2, varscan2
- DNM1L | c.*683_*684dup | 3'UTR (INS) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- DRAXIN | c.*2617A>T | 3'UTR (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
- DUS1L | c.398-25C>T | Intron (SNP) | VAF 21/216 reads (10%) | called by muse, mutect2
- EFL1 | c.*107T>G | 3'UTR (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- EHMT1 | c.*59G>C | 3'UTR (SNP) | VAF 19/30 reads (63%) | catalogued as rs1223159299; called by muse, mutect2, varscan2
- ENDOD1 | c.*1842T>A | 3'UTR (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- ENSA | c.57+316G>T | Intron (SNP) | VAF 55/1097 reads (5%) | called by muse, mutect2
- EPHA5 | c.*823A>G | 3'UTR (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- ERO1B | c.*2132A>G | 3'UTR (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- FER | c.*8820C>T | 3'UTR (SNP) | VAF 4/56 reads (7%) | catalogued as rs939199226; called by muse, mutect2
- FNBP1 | c.*2336G>C | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, varscan2
- FOXP1 | c.*3002C>T | 3'UTR (SNP) | VAF 30/69 reads (43%) | catalogued as rs566673921; called by muse, varscan2
- GABRA2 | c.187+18846dup | Intron (INS) | VAF 29/75 reads (39%) | catalogued as rs1435584240; called by mutect2, varscan2
- GATD1 | c.*747C>G | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- GDAP2 | c.*381T>C | 3'UTR (SNP) | VAF 47/48 reads (98%) | called by muse, mutect2, varscan2
- GSE1 | c.*1278A>T | 3'UTR (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- HACE1 | c.*1273A>T | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- HELLPAR | n.199289G>T | RNA (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- HLCS | chr21:36749445 del TGACTTTTTT | 3'Flank (DEL) | VAF 3/22 reads (14%) | catalogued as rs752325673; called by pindel, varscan2*
- HNRNPL | c.881-1247A>T | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- HPCAL4 | c.*3728dup | 3'UTR (INS) | VAF 39/141 reads (28%) | catalogued as rs1282685802; called by mutect2, pindel, varscan2
- IGF2 | chr11:2129358 G>T | 3'Flank (SNP) | VAF 48/146 reads (33%) | called by muse, mutect2, varscan2
- KSR1 | c.*1770del | 3'UTR (DEL) | VAF 117/287 reads (41%) | called by mutect2, pindel, varscan2
- LRRTM4 | chr2:76748062 G>T | 3'Flank (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- MAP1LC3B2 | c.*248T>A | 3'UTR (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2
- MAP9 | c.*2320A>T | 3'UTR (SNP) | VAF 30/56 reads (54%) | called by mutect2, varscan2
- MARK4 | c.1494+178A>G | Intron (SNP) | VAF 75/183 reads (41%) | catalogued as rs1215186278; called by muse, mutect2, varscan2
- MCM3AP | c.4290+1894del | Intron (DEL) | VAF 81/215 reads (38%) | called by mutect2, pindel, varscan2
- MCUB | c.*508A>G | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- MCUB | c.*509A>T | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- MLEC | c.-111C>T | 5'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- MLLT11 | c.*242C>G | 3'UTR (SNP) | VAF 141/319 reads (44%) | called by muse, mutect2, varscan2
- MRNIP | c.537+1199G>C | Intron (SNP) | VAF 84/173 reads (49%) | called by muse, mutect2, varscan2
- MYO5A | c.*908G>A | 3'UTR (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2, varscan2
- NCAM2 | c.*2758A>C | 3'UTR (SNP) | VAF 67/108 reads (62%) | called by muse, mutect2, varscan2
- NIN | chr14:50721463 A>C | 3'Flank (SNP) | VAF 15/16 reads (94%) | catalogued as COSV55396857; called by muse, mutect2, varscan2
- NIPBL | c.*950T>A | 3'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- NME6 | c.-7-594G>A | Intron (SNP) | VAF 45/130 reads (35%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+3582C>T | Intron (SNP) | VAF 69/117 reads (59%) | catalogued as rs961401016; called by muse, mutect2, varscan2
- NTRK3 | c.*10610del | 3'UTR (DEL) | VAF 33/81 reads (41%) | called by mutect2, pindel, varscan2
- NUCKS1 | c.*141C>T | 3'UTR (SNP) | VAF 45/426 reads (11%) | called by muse, mutect2
- NUDT12 | c.*1325G>A | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- NUGGC | c.*796T>A | 3'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- NUMA1 | c.129-78G>C | Intron (SNP) | VAF 42/92 reads (46%) | catalogued as rs997501126; called by muse, mutect2, varscan2
- PAX1 | c.*827A>T | 3'UTR (SNP) | VAF 92/181 reads (51%) | catalogued as rs1213145982; called by muse, mutect2, varscan2
- PAX6 | chr11:31789206 G>T | 3'Flank (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- PIKFYVE | c.*2029A>G | 3'UTR (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- PKD1L2 | n.2962T>C | RNA (SNP) | VAF 94/186 reads (51%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*4194G>A | 3'UTR (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2
- POLR3G | chr5:90514204 C>T | 3'Flank (SNP) | VAF 24/71 reads (34%) | catalogued as rs1267736954; called by muse, mutect2, varscan2
- PUDP | c.*104G>C | 3'UTR (SNP) | VAF 37/38 reads (97%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.*2979T>A | 3'UTR (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- RERG | c.*489C>G | 3'UTR (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- RFTN1 | c.*737G>T | 3'UTR (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- RGS2 | c.213-46G>A | Intron (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- ROR1 | c.*1322A>G | 3'UTR (SNP) | VAF 70/137 reads (51%) | called by muse, mutect2, varscan2
- RPS29 | c.-8A>C | 5'UTR (SNP) | VAF 122/128 reads (95%) | called by muse, mutect2, varscan2
- RTP1 | c.*197G>T | 3'UTR (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- SCN11A | c.387-13G>A | Intron (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- SCN2B | c.*3903C>A | 3'UTR (SNP) | VAF 37/413 reads (9%) | called by muse, mutect2
- SCN2B | c.*3091T>G | 3'UTR (SNP) | VAF 211/359 reads (59%) | called by muse, mutect2, varscan2
- SCN4B | c.*1856C>A | 3'UTR (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- SEC22A | c.*2220G>T | 3'UTR (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- SEMA3D | c.*584G>C | 3'UTR (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- SH2D1B | c.*1824A>C | 3'UTR (SNP) | VAF 5/71 reads (7%) | catalogued as rs1345267714; called by muse, mutect2
- SH3TC2 | c.3479-158G>A | Intron (SNP) | VAF 32/285 reads (11%) | called by muse, mutect2, varscan2
- SLC37A4 | c.984+215T>G | Intron (SNP) | VAF 56/94 reads (60%) | called by muse, mutect2, varscan2
- SLC5A3 | c.*4790A>T | 3'UTR (SNP) | VAF 59/119 reads (50%) | called by muse, mutect2, varscan2
- SLC6A7 | c.*789G>A | 3'UTR (SNP) | VAF 60/142 reads (42%) | called by muse, mutect2, varscan2
- SORT1 | c.*2034A>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- SP4 | c.*3232T>G | 3'UTR (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2, varscan2
- SPTSSB | c.*24G>A | 3'UTR (SNP) | VAF 15/285 reads (5%) | called by muse, mutect2
- SREK1 | chr5:66182448 T>C | 3'Flank (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*2751G>A | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.236+8046G>A | Intron (SNP) | VAF 83/168 reads (49%) | called by muse, mutect2, varscan2
- SYNE1 | c.26153+2324A>T | Intron (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- TMBIM1 | c.-40-3776C>T | Intron (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- TMEM235 | c.-314T>C | 5'UTR (SNP) | VAF 18/306 reads (6%) | called by muse, mutect2
- TMEM30A | c.*727T>C | 3'UTR (SNP) | VAF 49/88 reads (56%) | called by muse, mutect2, varscan2
- TMSB4X | c.-80G>A | 5'UTR (SNP) | VAF 166/168 reads (99%) | catalogued as COSV66081349; called by muse, mutect2, varscan2
- TRAF5 | c.*1901T>A | 3'UTR (SNP) | VAF 99/104 reads (95%) | called by muse, mutect2, varscan2
- TRIML2 | c.*45del | 3'UTR (DEL) | VAF 120/311 reads (39%) | catalogued as COSV100456188; called by mutect2, pindel, varscan2
- TSPYL4 | c.*691T>C | 3'UTR (SNP) | VAF 88/185 reads (48%) | called by muse, mutect2, varscan2
- UQCRC1 | chr3:48609663 C>G | 5'Flank (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- USP44 | c.*1057_*1084delinsCTAAAAGCTATCTATCTAAACTTGCA | 3'UTR (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2*
- VGLL3 | c.*4231G>C | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- VWC2L | c.*2729T>A | 3'UTR (SNP) | VAF 53/105 reads (50%) | called by muse, mutect2, varscan2
- WAC | c.42-19T>C | Intron (SNP) | VAF 29/30 reads (97%) | called by muse, varscan2
- WDR26 | c.928-42C>G | Intron (SNP) | VAF 58/59 reads (98%) | called by muse, mutect2, varscan2
- WDR36 | c.*1009A>G | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- WNT3A | c.*1707A>T | 3'UTR (SNP) | VAF 89/94 reads (95%) | called by muse, mutect2, varscan2
- ZBTB5 | c.*2413T>C | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- ZFHX3 | c.*2466A>T | 3'UTR (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- ZNF121 | c.*3496C>G | 3'UTR (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- ZNF490 | c.*305G>C | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, varscan2
- ZNF740 | c.*3686A>G | 3'UTR (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
